Gene-level copy-number profile of tumor specimen TCGA-QT-A5XL-01A from TCGA case TCGA-QT-A5XL, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 27.5 years (10,028 days).
Specimen TCGA-QT-A5XL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.d6fe5a5d-fa1f-4e40-a990-4ab74e507f70.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QT-A5XL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ec6407e2-a995-43ad-ae9d-84d31ba139df

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 6,592; copy number 3: 2,239; copy number 4: 50,233; copy number 5: 52; copy number 6: 587; copy number 7: 63; copy number 8: 13; copy number 9: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QT-A5XL-01A-11D-A35C-01): tumor purity 0.41, ploidy 3.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 39 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:66,533,383–66,924,856, 7 genes, copy number 9 (within-gene range 4–9): SGIP1, MIR3117, AL139147.1, TCTEX1D1, INSL5, DNAI4, AL592161.1.
- chr4:152,206,987–152,918,463, 17 genes, copy number 9 (within-gene range 4–9): AC079340.2, RN7SL446P, AC080078.1, AC080078.2, FBXW7, FBXW7-AS1, AC023424.2, MIR3140, MIR4453HG, MIR4453, RPS3AP18, AC023424.1, TMEM154, AC106882.1, TIGD4, ARFIP1, NSA2P6.
- chr12:26,335,352–26,833,194, 1 gene, copy number 9 (within-gene range 4–9): ITPR2.
- chr12:26,623,369–27,014,434, 6 genes, copy number 9: AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1.
- chr12:30,086,342–30,492,302, 8 genes, copy number 9: AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
